Surgical pathology report (de-identified scan), TCGA case TCGA-CG-4443, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-4443-01A (Primary Tumor).

■
Diagnosis/diagnoses:

Total gastrectomy preparation with inclusion of a moderately differentiated adenocarcinoma of the stomach (intestinal type) situated in the corpus and showing polypous exophytic growth with infiltration of the tunica submucosa. Tumor-free regional lymph nodes. Tumor-free oral and aboral resection margin. Tumor-free omentum. In the antrum also circumscribed relatively high-grade mucosal edema with pseudopolypous foveolar hyperplasia and in the junction between the antrum and the corpus a small lipid islet.

Tumor stage: pT1 pN0 (0/30) pMX; ■

Source: NCI Genomic Data Commons file 447fc673-933b-47bd-984c-f22e4a1bf857 (TCGA-CG-4443.C80CFCF9-A673-4A31-BCE0-487939F51181.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).